MMRF case MMRF_1912 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/c5c5d3ed-a093-4550-8370-160dbef3e13b

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 58 years; Vital status: Dead; Days to death: 389 days (1.1 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 58.0 years (21,197 days); ISS stage: III; Days to last known disease status: 389 days (1.1 years); Days to last follow up: 389 days (1.1 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 127 days.
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 128 days; Days to treatment end: 204 days.
   Treatment given: Therapeutic agents: Carfilzomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 211 days; Days to treatment end: 341 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 389.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -10 (ECOG 0): M Protein 4.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.0267 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 29 mg/dL; Immunoglobulin G 2.3 g/L; Immunoglobulin A 50.1 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 8.93 µg/mL; Lactate Dehydrogenase 2.62 µkat/L; Hemoglobin 5.64 mmol/L; Leukocytes 8.9 ×10⁹/L; Absolute Neutrophil 5.4 ×10⁹/L; Platelets 94 ×10⁹/L; Creatinine 193 µmol/L; Blood Urea Nitrogen 9.64 mmol/L; Calcium 2.6 mmol/L; Albumin 30 g/L; Total Protein 10.7 g/dL; Glucose 8.42 mmol/L; C-Reactive Protein 0.271 mg/dL.
- Day 85 (ECOG 0): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.0267 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.34 mg/dL; Immunoglobulin G 2.87 g/L; Immunoglobulin A 6.29 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 2.48 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 7.7 ×10⁹/L; Absolute Neutrophil 5.8 ×10⁹/L; Platelets 230 ×10⁹/L; Creatinine 87.5 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.35 mmol/L; Albumin 36 g/L; Total Protein 6.3 g/dL; Glucose 6.22 mmol/L.
- Day 176 (ECOG 0): M Protein 0.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.0275 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.72 mg/dL; Immunoglobulin G 2.64 g/L; Immunoglobulin A 14.6 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 2.78 µg/mL; Lactate Dehydrogenase 2.05 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 6.6 ×10⁹/L; Absolute Neutrophil 4.8 ×10⁹/L; Platelets 239 ×10⁹/L; Creatinine 92.8 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.45 mmol/L; Albumin 39 g/L; Total Protein 6.9 g/dL; Glucose 6.66 mmol/L.
- Day 267 (ECOG 0): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.0276 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.11 mg/dL; Immunoglobulin G 2.15 g/L; Immunoglobulin A 7.67 g/L; Immunoglobulin M 0.25 g/L; Hemoglobin 7.56 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 310 ×10⁹/L; Creatinine 105 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.33 mmol/L; Albumin 37 g/L; Total Protein 7 g/dL; Glucose 7.7 mmol/L.
- Day 353 (ECOG 4): M Protein 1.5 g/dL; Hemoglobin 5.58 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 66 ×10⁹/L; Creatinine 205 µmol/L; Blood Urea Nitrogen 11.4 mmol/L; Calcium 1.88 mmol/L; Albumin 23 g/L; Total Protein 8.2 g/dL; Glucose 7.48 mmol/L.

Other clinical attributes
- Day -10: Weight: 98 kg; Height: 175 cm.

Family history
- Relative with cancer history: no.

Biospecimens (4 samples)
- Sample MMRF_1912_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -10 days.
- Sample MMRF_1912_1_PB_CD138pos: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS; Days to sample procurement: -10 days.
- Sample MMRF_1912_1_PB_CD3pos: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -10 days.
- Sample MMRF_1912_3_PB_CD138pos: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS; Days to sample procurement: 353 days.
